Surgical pathology report (de-identified scan), TCGA case TCGA-J4-AATV, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-AATV-01A (Primary Tumor).

[page 1 of 5]
Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Source of Specimen

- A. RIGHT PELVIC NODES FS-
- B. RIGHT PELVIC NODES NFS-
- C. LEFT PELVIC NODES FS-
- D. LEFT PELVIC NODES NFS-
- E. PROSTATE GLAND, SEMINAL VESICLES, VASA DEFERENTIA-

FINAL DIAGNOSIS:

- A. RIGHT PELVIC NODES FS-
TWO LYMPH NODES WITH NO TUMOR SEEN (0/2).
- B. RIGHT PELVIC NODES NFS-
RESIDUAL LYMPH NODE AND FIBROFATTY TISSUES WITH NO TUMOR SEEN.
- C. LEFT PELVIC NODES FS-
TWO LYMPH NODES WITH NO TUMOR SEEN (0/2).
- D. LEFT PELVIC NODES NFS-
RESIDUAL LYMPH NODE AND FIBROFATTY TISSUES WITH NO TUMOR SEEN.
- E. PROSTATE GLAND, SEMINAL VESICLES, VASA DEFERENTIA-
ADENOCARCINOMA OF PROSTATE (see synoptic report below).
SEMINAL VESICLES WITH AMYLOID DEPOSITION.

IMMUNOSTAINS FOR K-903, P63, AND P504S EXAMINED ON BLOCK E15.

CONGO RED STAIN EXAMINED ON BLOCK E23.

RESULTS INCORPORATED IN ABOVE DIAGNOSES.

Internal positive elements were examined and/or appropriate positive controls were stained along side sections from this case. The control tissue was examined and judged to be technically acceptable.

SYNOPTIC REPORT:

Prepared for

ICD6-3
Adenocarcinoma NOS 8140/3 Final
Site: Prostate NOS C61.9
7/28/14

[page 2 of 5]
ADENOCARCINOMA OF PROSTATE

TUMOR SITE: BILATERAL

SPECIMEN TYPE: RADICAL PROSTATECTOMY

WEIGHT: 39 GRAMS

SIZE: 4 x 3.5 x 3 CM

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 3 = 6/10

SEVERITY IN EXTENT OF TUMOR: 4 /5

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 4

TNM STAGE: AT LEAST pT2c (SEE COMMENT), pN0, pMx

LYMPHATIC (SMALL VESSEL) INVASION: NOT FOUND

PERINEURAL INVASION: PRESENT

NO TUMOR SEEN IN SEMINAL VESICLES.

MARGIN STATUS:

- POSITIVE INKED MARGINS: RIGHT POSTERIOR PROSTATE (SLIDES E15 AND E21) SEE COMMENT
- NO TUMOR SEEN AT OTHER SPECIMEN MARGINS

COMMENT:

1. THE POSITIVE MARGIN APPEARS TO BE DISRUPTED POSSIBLY BY AN IATROGENIC INCISION
2. THERE IS NO EXTRAPROSTATIC INVASION SEEN ELSEWHERE
3. FURTHER CLINICAL CORRELATION IS NEEDED

Signature

(Case signed

Signed Others

Frozen Section

- A. RIGHT PELVIC LYMPH NODES, FS: 2 NODES. NO CARCINOMA SEEN.
LEFT PELVIC LYMPH NODES, FS: 2 NODES. NO CARCINOMA SEEN.
-

[page 3 of 5]
FS performed b -

(Frozen Section Signed

Case Clinical Information
PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "right pelvic nodes-FS" are two gray/tan frozen section tissue fragments measuring 1.2 x 0.7 cm. Wrapped and entirely submitted in A1.

B. Received in formalin labeled with the patient's name and "right pelvic nodes-NFS" is an aggregate of yellow fibrofatty tissue fragments measuring 5 x 0.5 x 0.5 cm. The fat is trimmed and four probable lymph nodes are grossly identified. The largest measures 1 x 0.7 cm; the smallest, 0.5 x 0.2 cm. Wrapped and entirely submitted in B1.

C. Received in formalin labeled with the patient's name and "left pelvic lymph nodes-FS" are two gray/tan frozen section tissue fragments. The larger measures 1.7 x 0.8 cm; the smaller, 1.2 x 0.6 cm. Wrapped and entirely submitted in C1.

D. Received in formalin labeled with the patient's name and "left pelvic nodes-NFS" is an aggregate of yellow fibrofatty tissue fragments measuring 4 x 2 x 0.5 cm. The fat is trimmed and three probable lymph nodes are grossly identified. The largest measures 2 x 1.2 cm; the smallest, 1.2 x 0.5 cm. Wrapped and entirely submitted in D1, D2.

E. Received in formalin labeled "prostate gland, seminal vesicles and vasa deferentia" is a radical prostatectomy specimen which includes a 39 gram prostate gland with attached seminal vesicles and vasa deferentia. The prostate gland measures 4 x 3.5 x 3 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 2 x 1.5 cm. The right vas measures 1.5 x 0.5 cm. The left seminal vesicle measures 2 x 1.5 cm. The left vas measures 1.5 x 0.5 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in E1-E6; bladder resection margin shaved and serially

[page 4 of 5]
sectioned in E7, E8; complete section of mid gland anterior in E9, E10; posterior in E11, E12; complete section of upper third of gland, anterior in E13, E14; posterior in E15, E16; remainder of the posterior gland entirely submitted in E17-E22; right seminal vesicle and vas deferens in E23; and left seminal vesicle and vas deferens in E24.

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK
H&E X1
B. AA ROUTINE H&E X1 BLOCK
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
E. AA ROUTINE H&E X1 BLOCK.5
H&E X1
E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
E. AA ROUTINE H&E X1 BLOCK.7
H&E X1
E. AA ROUTINE H&E X1 BLOCK.8
H&E X1
E. AA ROUTINE H&E X1 BLOCK.9
H&E X1
E. AA ROUTINE H&E X1 BLOCK.10
H&E X1
E. AA ROUTINE H&E X1 BLOCK.11
H&E X1
E. AA ROUTINE H&E X1 BLOCK.12
H&E X1
E. AA ROUTINE H&E X1 BLOCK.13
H&E X1
E. AA ROUTINE H&E X1 BLOCK.14

Prepared for

[page 5 of 5]
H&E X1
E. AA ROUTINE H&E X1 BLOCK.15
H&E X1 PRST 3AB
E. AA ROUTINE H&E X1 BLOCK.16
H&E X1
E. AA ROUTINE H&E X1 BLOCK.17
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.18
H&E X1
E. AA ROUTINE H&E X1 BLOCK.19
H&E X1
E. AA ROUTINE H&E X1 BLOCK.20
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.21
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.22
H&E X1
E. AA ROUTINE H&E X1 BLOCK.23
H&E X1 CONGO RED
E. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Prepared for.

Source: NCI Genomic Data Commons file e3ee8e32-59af-453b-bda1-125c24807918 (TCGA-J4-AATV.860F2174-869F-47E4-ABC1-14E4F608669A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).